Somatic mutation profile of tumor specimen ALCH-B57F-TTP1-A (aliquot ALCH-B57F-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B57F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.8 years (25,112 days).
Specimen ALCH-B57F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 810d22b6-07df-466d-801b-197a75245dbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B57F-NB1-A (Blood Derived Normal), aliquot ALCH-B57F-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c02355c4-a8f6-4e9b-ab56-314602ce26da

The open-access MAF lists 566 somatic variants for this specimen: 365 protein-altering or splice-affecting, 123 silent, 78 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 315, Silent 123, Intron 43, Nonsense Mutation 29, RNA 14, 5'UTR 11, Splice Site 7, Frame Shift Del 7, 3'UTR 6, Splice Region 5, 3'Flank 3, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 20/109 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA1 | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66065244; called by muse, mutect2, varscan2
- ABCA13 | c.2357C>G p.S786C | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV70028807; called by muse, mutect2, varscan2
- AC126283.2 | c.1305G>T p.M435I | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV67098207; called by muse, mutect2, varscan2
- ACSM2A | c.420G>A p.M140I (on ENST00000219054; = p.M61I on NM_001308169.2) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV54584565; called by muse, varscan2
- AGBL1 | c.3294C>G p.F1098L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | PolyPhen benign (0.023); catalogued as rs1053214943, COSV66852612; called by muse, mutect2, varscan2
- AGTR1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.313); catalogued as rs760594254; called by mutect2, varscan2
- AHRR | c.852G>T p.R284S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV57088126; called by muse, mutect2, varscan2
- AIDA | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs751365285; called by muse, mutect2, varscan2
- AL353753.1 | n.764C>A | Splice Region (SNP) | VAF 21/126 reads (17%) | catalogued as rs1004233595; called by muse, varscan2
- APOB | c.11182G>C p.D3728H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51923344; called by muse, mutect2, varscan2
- ARID1A | c.3276G>C p.L1092F | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61370761; called by muse, mutect2, varscan2
- ARL16 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1490722734, COSV61267127; called by muse, varscan2
- ASXL3 | c.1791C>A p.D597E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs1196852422; called by muse, mutect2, varscan2
- ATP8B1 | c.3668C>T p.S1223F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99377921; called by muse, mutect2, varscan2
- BSN | c.9446C>T p.S3149L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as rs755682920, COSV99607757; called by muse, varscan2
- CADM3 | c.964G>T p.V322L (on ENST00000368125 / NM_001127173.3; = p.V356L on NM_021189.5) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs945248335; called by mutect2, varscan2
- CALML5 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66702623; called by muse, mutect2, varscan2
- CCDC73 | c.2725C>A p.P909T | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV58800330, COSV58806640; called by muse, mutect2, varscan2
- CDK12 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.945); catalogued as rs1294329419, COSV71000414, COSV71000736; called by muse, mutect2, varscan2
- CDK13 | c.2841C>G p.F947L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV51698598, COSV99475488; called by muse, mutect2, varscan2
- CENPQ | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.524); catalogued as COSV59921639; called by muse, mutect2, varscan2
- CFAP44 | c.1627C>G p.L543V | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV55611178; called by muse, mutect2, varscan2
- CLCA1 | c.2680C>A p.P894T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as rs1389987571, COSV52329399; called by muse, varscan2
- CLCA4 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV55369196; called by muse, mutect2
- CLEC7A | c.554G>T p.R185L (on ENST00000304084 / NM_197947.3; = p.R139L on NM_022570.5) | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.88); catalogued as COSV53721385; called by muse, mutect2, varscan2
- CLEC7A | c.553C>T p.R185W (on ENST00000304084 / NM_197947.3; = p.R139W on NM_022570.5) | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53721984; called by muse, mutect2, varscan2
- CLTCL1 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs782166058; called by muse, mutect2
- CLU | c.585C>G p.F195L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.709); catalogued as COSV57066247; called by muse, mutect2, varscan2
- COQ8A | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs145422777; called by muse, mutect2, varscan2
- CPEB4 | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1452256661; called by muse, mutect2, varscan2
- CPED1 | c.2801C>G p.T934R | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60007522; called by muse, mutect2
- CST3 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV65362182; called by muse, mutect2, varscan2
- CST8 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV55671842, COSV55672164; called by muse, mutect2
- CTNNB1 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV104442210; called by muse, mutect2
- CUEDC2 | c.72C>G p.L24= | Splice Region (SNP) | VAF 9/45 reads (20%) | catalogued as rs748773100; called by muse, mutect2, varscan2
- CUX2 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV55633068; called by muse, mutect2, varscan2
- CYP7A1 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.43); catalogued as rs1459584618; called by muse, mutect2, varscan2
- DMD | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99924775; called by muse, mutect2
- DNMBP | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs746750816; called by muse, mutect2, varscan2
- DNMT3A | c.995del p.G332Efs*13 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs1358218642, COSV53047626, COSV53084733; called by mutect2, pindel, varscan2
- DSG1 | c.1947G>C p.E649D | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.505); catalogued as rs867930449; called by muse, mutect2, varscan2
- DZIP1L | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV100551288; called by muse, mutect2, varscan2
- EPB41L3 | c.2365G>C p.G789R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV59458167; called by muse, mutect2, varscan2
- ERAL1 | c.537-3C>G | Splice Region (SNP) | VAF 22/140 reads (16%) | catalogued as COSV99650516; called by muse, varscan2
- FADS2 | c.654C>G p.F218L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as CM142394; called by muse, mutect2
- FADS6 | c.1023C>A p.Y341* | Nonsense Mutation (SNP) | VAF 14/135 reads (10%) | catalogued as rs1158971491; called by muse, mutect2, varscan2
- FAM161A | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs781246093; called by muse, mutect2, varscan2
- FANCA | c.3677C>G p.S1226* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as CM161194; called by muse, mutect2, varscan2
- FGF16 | c.556T>A p.F186I | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71546231; called by muse, mutect2, varscan2
- FIG4 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | catalogued as rs78382144; called by muse, mutect2, varscan2
- FLG | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.599); catalogued as COSV64243385, COSV64245208; called by muse, mutect2
- FMNL2 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.221); catalogued as rs1474435422; called by muse, mutect2
- GSDME | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100742431; called by muse, mutect2, varscan2
- HGF | c.2008G>A p.E670K | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55944710, COSV55959180; called by muse, mutect2, varscan2
- HTR2A | c.180C>A p.C60* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV66327382; called by muse, mutect2, varscan2
- IGF2BP1 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.288); catalogued as COSV51735201; called by muse, mutect2, varscan2
- IRS4 | c.1817G>C p.R606P | Missense Mutation (SNP) | VAF 73/424 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV64532547, COSV64533324; called by muse, mutect2, varscan2
- ITGBL1 | c.505G>T p.G169* | Nonsense Mutation (SNP) | VAF 8/139 reads (6%) | catalogued as COSV101095774; called by muse, mutect2
- ITGBL1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV66009702; called by muse, mutect2
- IZUMO3 | c.226G>C p.A76P | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.26); catalogued as COSV101371520; called by muse, mutect2
- KAT6B | c.3173G>C p.R1058P | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV54743248; called by muse, mutect2, varscan2
- KCNMA1 | c.2348C>T p.P783L (on ENST00000286628 / NM_001161352.2; = p.P725L on NM_002247.4) | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.148); catalogued as rs1256917325; called by mutect2, varscan2
- KIAA2026 | c.2965G>T p.A989S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.022); catalogued as COSV67356485; called by muse, mutect2, varscan2
- KIR3DX1 | n.1006+1G>T | Splice Site (SNP) | VAF 12/100 reads (12%) | catalogued as COSV55598340; called by muse, mutect2, varscan2
- KITLG | c.527G>C p.R176T | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57200567; called by muse, mutect2
- KRT6B | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs756538750, COSV52881720; called by muse, mutect2, varscan2
- LAMA1 | c.1397C>A p.P466H | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs764850566; called by muse, mutect2, varscan2
- LONRF3 | c.2033C>T p.A678V (on ENST00000371628 / NM_001031855.3; = p.A637V on NM_024778.5) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs767610350; called by muse, mutect2, varscan2
- LPAR4 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.947); catalogued as rs764055600, COSV70912356; called by muse, mutect2
- LRRC34 | c.322A>G p.T108A | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs772670669; called by muse, mutect2, varscan2
- LRRFIP1 | c.1641G>A p.M547I (on ENST00000392000 / NM_001137552.2; = p.M523I on NM_004735.4) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs750534165; called by muse, mutect2, varscan2
- MAGEB2 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1318845439; called by muse, mutect2, varscan2
- MED12 | c.4154C>A p.A1385D | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV61357302; called by mutect2, varscan2
- METTL21A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs901422059, COSV55881197; called by mutect2, varscan2
- MFSD14A | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV64514640; called by muse, mutect2
- MTDH | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100292608; called by muse, mutect2, varscan2
- MUC16 | c.38769G>T p.M12923I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV67446785; called by muse, varscan2
- MUC17 | c.11054C>A p.P3685Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60284086; called by muse, mutect2, varscan2
- MYH7 | c.2206A>T p.I736F | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516138, CM109191; called by muse, mutect2
- MYLK2 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.799); catalogued as COSV65658752; called by muse, mutect2, varscan2
- NBEAL1 | c.6332G>A p.R2111H | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356656046, COSV68915749, COSV68916103; called by muse, mutect2, varscan2
- NIN | c.5524G>A p.D1842N (on ENST00000382041 / NM_182946.1; = p.D1129N on NM_016350.4) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs765795570; called by muse, mutect2, varscan2
- NIN | c.3727G>C p.E1243Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1566811366; called by muse, mutect2, varscan2
- NLRP5 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as rs1003142647; called by muse, mutect2, varscan2
- NOL8 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as rs1410842202; called by muse, mutect2, varscan2
- NUP160 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV65856314; called by muse, mutect2, varscan2
- OCRL | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 9/96 reads (9%) | catalogued as CM139704; called by muse, mutect2
- OR1N2 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV65460137; called by muse, mutect2, varscan2
- OR5AS1 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV57981437, COSV57983607; called by muse, mutect2, varscan2
- PADI4 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); catalogued as rs763896520, COSV64925196; called by mutect2, varscan2
- PCLO | c.14717A>T p.Q4906L | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61645061; called by muse, mutect2, varscan2
- PCYOX1 | c.1237C>G p.L413V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs565888631; called by muse, mutect2, varscan2
- PDE3B | c.2061G>C p.K687N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.301); catalogued as COSV56379901; called by muse, mutect2, varscan2
- PIK3CG | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751048583, COSV63253111, COSV63253408; called by mutect2, varscan2
- PLCB1 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100568944; called by muse, varscan2
- POM121L12 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV68692478; called by muse, mutect2, varscan2
- PPFIA1 | c.3371G>A p.R1124K | Missense Mutation (SNP) | VAF 39/405 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV54141437; called by muse, mutect2, varscan2
- PRKD3 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745406511; called by muse, varscan2
- PRTG | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV66837115; called by muse, mutect2
- PXDNL | c.2153G>T p.C718F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62487398; called by muse, mutect2, varscan2
- RADX | c.2061G>C p.E687D | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1033181298, COSV65319426; called by muse, mutect2
- RBM10 | c.995G>C p.R332P | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV61311387, COSV99051447; called by muse, mutect2, varscan2
- REV1 | c.2722G>C p.E908Q | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.261); catalogued as rs866369064, COSV99176788; called by muse, mutect2, varscan2
- RGPD4 | c.3900G>C p.L1300F | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.94); catalogued as rs1336055278; called by muse, mutect2, varscan2
- RGS12 | c.2797G>C p.E933Q | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58752804, COSV58752996; called by muse, mutect2
- RGS3 | c.606C>G p.H202Q (on ENST00000350696 / NM_001282923.2; = p.H90Q on NM_017790.4) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs542813496, COSV58280654; called by mutect2, varscan2
- RNF144A | c.14G>T p.R5M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.735); catalogued as COSV57982502; called by muse, mutect2, varscan2
- RSRC1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as rs773589303; called by muse, mutect2, varscan2
- RYR2 | c.10868G>T p.G3623V | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1315764018, COSV63666611; called by muse, mutect2, varscan2
- SAGE1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as rs181135819, COSV61012942, COSV61016070; called by muse, mutect2
- SAMD15 | c.1627C>T p.L543F | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV53625351; called by muse, mutect2
- SIGLEC10 | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.255); catalogued as rs1198803241; called by muse, mutect2, varscan2
- SLC25A17 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54352092; called by mutect2, varscan2
- SLITRK2 | c.1937G>T p.R646L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59427731; called by muse, mutect2, varscan2
- SPRY3 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV57143872; called by muse, mutect2
- STRC | c.4645G>C p.V1549L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs751656051; called by muse, mutect2, varscan2
- TCEAL3 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1337129404; called by mutect2, varscan2
- TIMMDC1 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 9/108 reads (8%) | catalogued as COSV99956169; called by muse, mutect2
- TNR | c.1909C>T p.H637Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs994865157, COSV54887868; called by muse, mutect2, varscan2
- TOPORS | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779292250, COSV62118603; called by muse, mutect2, varscan2
- TPO | c.1768+1G>T p.X590_splice | Splice Site (SNP) | VAF 6/59 reads (10%) | catalogued as CS002687; called by muse, mutect2, varscan2
- TRAJ31 | c.2G>A p.*1= | Missense Mutation (SNP) | VAF 6/130 reads (5%) | catalogued as rs1240870645; called by muse, mutect2
- TSKU | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV60751215; called by muse, mutect2, varscan2
- UFD1 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54251098; called by muse, mutect2
- UNC5C | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs762175329, COSV71659626; called by muse, mutect2, varscan2
- USP15 | c.533G>C p.R178T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54793770; called by muse, mutect2
- WASHC2A | c.1651C>G p.Q551E | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.605); catalogued as COSV99254489; called by muse, mutect2
- XIRP2 | c.5662G>T p.G1888C (on ENST00000628543; = p.G2063C on NM_152381.6) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV99743391; called by muse, mutect2
- ZMAT3 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 33/248 reads (13%) | catalogued as rs1364064523; called by muse, mutect2, varscan2
- ZNF765 | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV67182144; called by muse, mutect2
- ZNF775 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1370316012; called by mutect2, varscan2
- ABI3BP | c.1406C>A p.P469H | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- AC244197.3 | c.911C>G p.S304C | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- ACACA | c.2198T>C p.I733T | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.71); called by muse, mutect2
- ADAMTS8 | c.2451G>C p.Q817H | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4346G>A p.R1449K | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADCY1 | c.2274del p.L759Sfs*51 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel, varscan2
- ADPRHL1 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- AGMO | c.646A>C p.N216H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP6 | c.3212T>A p.L1071Q | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ANKRD18A | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- APBA1 | c.2108G>C p.G703A | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AQP12A | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARFGEF1 | c.1413C>G p.F471L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.717); called by muse, varscan2
- ARHGAP39 | c.1877G>A p.G626D | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- ARHGEF5 | c.4132G>C p.E1378Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ARID3A | c.24G>C p.E8D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); called by muse, varscan2
- ARID5B | c.2023A>T p.T675S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ARL2BP | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- B4GALNT3 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BAG6 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- BCORL1 | c.2656G>T p.E886* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- BDNF | c.441G>A p.W147* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- BRCC3 | c.493-1G>T p.X165_splice | Splice Site (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- C16orf78 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C1GALT1 | c.537G>C p.L179F | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CC2D1B | c.2191C>A p.H731N | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CCDC66 | c.2227G>C p.E743Q (on ENST00000394672 / NM_001353147.1; = p.E709Q on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CCL24 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD109 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD177 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD200R1L | c.333G>C p.Q111H | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CD276 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.391); called by muse, mutect2
- CDHR3 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.339); called by muse, mutect2
- CDK12 | c.2983G>C p.D995H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CEP83 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- CHD8 | c.2164G>C p.D722H (on ENST00000646647 / NM_001170629.2; = p.D443H on NM_020920.4) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHEK2 | c.856T>A p.C286S (on ENST00000382580 / NM_001005735.2; = p.C243S on NM_007194.4) | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CLCA1 | c.2681C>A p.P894H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, varscan2
- CMIP | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- COG1 | c.2881G>C p.E961Q | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- COL4A1 | c.4201G>T p.D1401Y | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2
- CPT1C | c.771+1G>T p.X257_splice | Splice Site (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- CSF2RB | c.1272C>G p.I424M | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2
- CXorf56 | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- DENR | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- DMXL1 | c.302G>T p.W101L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH6 | c.6656G>T p.R2219L | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNHD1 | c.1785+8G>C | Splice Region (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- DNMT3A | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.486); called by mutect2, varscan2
- EGFL6 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.201); called by muse, varscan2
- ELF4 | c.534C>A p.I178= | Splice Region (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- EPB41L5 | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- EPOR | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- EVC | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- F8 | c.2247G>T p.L749F | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- FAM135B | c.3489A>T p.E1163D | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FAM160A1 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- FAM47C | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FAT2 | c.5155G>C p.D1719H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAT2 | c.1889C>T p.A630V | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBN2 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- FBXO21 | c.1033G>C p.D345H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXO33 | c.1522G>C p.D508H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FIGNL1 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by mutect2, varscan2
- FKBP9 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- FRS2 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2
- GABRG3 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.094); called by muse, varscan2
- GK | c.311C>A p.T104N | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLT1D1 | c.752C>G p.S251C (on ENST00000442111 / NM_001366889.1; = p.S171C on NM_144669.3) | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLUD2 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- GRIK4 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GRIN2B | c.3515C>A p.P1172H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- GZMA | c.26C>A p.A9E | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.421); called by muse, mutect2
- HBS1L | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HCN1 | c.683C>G p.S228* | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- HEATR5A | c.5921G>C p.R1974T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2
- HEATR5A | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- HECTD4 | c.6979G>C p.V2327L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HELZ2 | c.3976G>T p.E1326* (on ENST00000467148 / NM_001037335.2; = p.E757* on NM_033405.3) | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- HMGB4 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2
- HOOK3 | c.1531A>T p.R511W | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HR | c.2624C>T p.S875L | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- HR | c.2623T>A p.S875T | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- HRG | c.23T>G p.L8R | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HRG | c.644T>A p.F215Y | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HS3ST5 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HUWE1 | c.10303A>C p.M3435L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- IDNK | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLL5 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2
- IGSF1 | c.2946del p.M983Wfs*16 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- IGSF10 | c.2491A>T p.S831C | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- IKZF1 | c.492C>G p.I164M | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- IL1RAP | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2
- ISG20L2 | c.686G>A p.W229* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | called by mutect2, varscan2
- KANSL2 | c.1235A>C p.D412A | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); called by mutect2, varscan2
- KIR2DL4 | c.1133G>C p.R378T (on ENST00000396284; = p.R304T on NM_001080770.2) | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KLHL7 | c.1467G>C p.Q489H (on ENST00000339077 / NM_001031710.3; = p.Q441H on NM_018846.5) | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.13); called by muse, varscan2
- KRTAP5-8 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2
- LGR4 | c.2460del p.K821Rfs*35 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- LHFPL1 | c.248T>A p.M83K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- LLGL1 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH3 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- LRP1B | c.9749C>T p.S3250L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC6 | c.1190C>G p.T397S | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTO1 | c.398+1G>A p.X133_splice | Splice Site (SNP) | VAF 11/257 reads (4%) | called by muse, mutect2
- MAP1A | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- MED14 | c.538C>G p.P180A | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- MET | c.3791C>G p.S1264* | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- MFN1 | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.087); called by muse, mutect2
- MFN1 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.575); called by muse, mutect2
- MGA | c.5959G>T p.E1987* (on ENST00000219905 / NM_001164273.1; = p.E1778* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- MRC1 | c.3667C>A p.P1223T | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MXRA5 | c.8098G>C p.E2700Q | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.111); called by muse, mutect2
- MXRA5 | c.7760G>T p.G2587V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYBPC1 | c.2230A>T p.I744F (on ENST00000550270 / NM_206820.2; = p.I769F on NM_002465.4) | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MYCBP2 | c.323C>G p.S108C (on ENST00000357337; = p.S146C on NM_015057.5) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYH2 | c.3356C>A p.A1119D | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH3 | c.5362G>A p.E1788K | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- MYH6 | c.2434G>T p.A812S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2
- MYH6 | c.1812G>C p.E604D | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.207); called by muse, mutect2
- MYO5A | c.5526G>C p.Q1842H | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NAALADL2 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- NBAS | c.3428A>T p.H1143L | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2
- NFIA | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKAPL | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NOBOX | c.605C>A p.A202D | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NRBP1 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by mutect2, varscan2
- NSD1 | c.4048C>T p.P1350S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NSMAF | c.940C>G p.Q314E | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NUDT19 | c.728C>G p.S243* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- NUP42 | c.1127C>G p.S376* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- NVL | c.1417G>T p.D473Y | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10AD1 | c.522C>A p.H174Q | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.824); called by muse, mutect2
- OR13F1 | c.679A>G p.R227G | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- OR5W2 | c.207T>A p.C69* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- OR7E24 | c.717T>G p.I239M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR8G1 | c.179A>T p.Y60F | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- OR8K1 | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); called by muse, mutect2
- PCDHA8 | c.2114G>T p.C705F | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PCDHB1 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCDHB12 | c.1228_1230delinsAG p.D410Rfs*22 | Frame Shift Del (DEL) | VAF 26/170 reads (15%) | called by pindel, varscan2*
- PCDHGA4 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCSK5 | c.4797G>T p.E1599D | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PDE8B | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PIGS | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PITX1 | c.776C>A p.P259Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); called by mutect2, varscan2
- PJA2 | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.547); called by muse, mutect2
- PLA2G4F | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB4 | c.1572C>A p.D524E | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNLIPRP2 | c.1068+2G>A | Missense Mutation (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- POLR3A | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- PPM1G | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.025); called by mutect2, varscan2
- PRAMEF19 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PREPL | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.085); called by muse, mutect2
- PREX1 | c.1440del p.D481Tfs*10 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- PRKAA2 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRODH2 | c.1207G>T p.D403Y (on ENST00000301175; = p.D327Y on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by mutect2, varscan2
- PRSS55 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSG9 | c.413T>A p.F138Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPN21 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- RALBP1 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.876); called by muse, varscan2
- RBM44 | c.628G>C p.E210Q (on ENST00000611254; = p.E844Q on NM_001080504.2) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- RBP3 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF114 | c.418A>T p.T140S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RPS6KA6 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RPUSD1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.097); called by muse, varscan2
- RTF1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RTF2 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- RTTN | c.2309+1G>T p.X770_splice | Splice Site (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- RYR2 | c.729G>T p.E243D | Missense Mutation (SNP) | VAF 15/170 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); called by muse, mutect2
- SCAF8 | c.2479C>T p.L827F | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SCARB1 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SEMA3A | c.1703C>G p.S568* | Nonsense Mutation (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- SEPTIN1 | c.738C>A p.Y246* (on ENST00000321367; = p.Y199* on NM_052838.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- SETD1B | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.093); called by muse, varscan2
- SF3A1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- SH3GL1 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC12A5 | c.3050A>G p.E1017G (on ENST00000454036 / NM_001134771.2; = p.E994G on NM_020708.5) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- SLC4A1 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC4A3 | c.1907G>T p.R636L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by mutect2, varscan2
- SLC7A3 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC8A1 | c.230G>T p.R77I | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLF1 | c.2354C>T p.S785L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- SNX12 | c.171C>A p.N57K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SPEN | c.6820G>C p.E2274Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SPOCD1 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- SPTA1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SRCAP | c.4969C>G p.P1657A | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SRRM2 | c.1936A>T p.R646W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SRSF2 | c.365_379del p.P122_R126del | In Frame Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- SSBP3 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- STIL | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2
- STK36 | c.2544C>G p.F848L | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, varscan2
- SUPT5H | c.485C>G p.S162* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- SYT4 | c.247A>T p.N83Y | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TADA1 | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- TANGO6 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBC1D32 | c.3513G>C p.W1171C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THADA | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THBS3 | c.914C>G p.P305R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.093); called by muse, varscan2
- THOC2 | c.119C>G p.S40* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- TLK2 | c.1235G>C p.R412T (on ENST00000326270 / NM_001284333.2; = p.R390T on NM_006852.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TMEM161B | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TPTE2 | c.66-2A>G p.X22_splice | Splice Site (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- TRAV26-1 | c.129del p.I44Sfs*25 | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | called by mutect2, pindel, varscan2
- TRIM29 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TRIP11 | c.1539G>C p.L513F | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); called by muse, mutect2
- TRPC4 | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.792); called by muse, mutect2
- UBL7 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- UGGT2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2
- USH1C | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- USP27X | c.681G>A p.W227* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- USP6NL | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- VPS26A | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- VPS45 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR97 | c.2258G>T p.C753F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- XPOT | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); called by muse, mutect2
- ZFHX4 | c.9668C>T p.S3223L | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ZNF12 | c.1613G>C p.R538T (on ENST00000405858 / NM_016265.4; = p.R500T on NM_006956.3) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- ZNF233 | c.1747C>G p.Q583E | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ZNF441 | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.664); called by muse, mutect2
- ZNF48 | c.708C>G p.I236M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF518B | c.2454G>T p.Q818H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZNF558 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF584 | c.906A>C p.E302D | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.072); called by muse, mutect2
- ZNF7 | c.1161G>C p.E387D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF7 | c.1378C>G p.Q460E | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- ZNF761 | c.2141G>C p.G714A | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); called by muse, mutect2
- ZNF8 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- ZNF800 | c.238G>T p.G80* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- ZNF816 | c.1682G>C p.G561A | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCB4 | c.1035C>T p.F345= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- ABCC8 | c.793C>A p.R265= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV56846348; called by muse, mutect2, varscan2
- AC008397.2 | c.765G>A p.G255= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- ADAMTSL4 | c.2394G>C p.R798= | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, varscan2
- ARHGEF7 | c.366C>T p.L122= (on ENST00000375741 / NM_001113511.2; = p.L101= on NM_145735.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- ATP1A2 | c.69G>A p.K23= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, varscan2
- AZGP1 | c.459C>T p.A153= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- BUB1B | c.1788C>T p.F596= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as rs1323236014; called by muse, mutect2, varscan2
- CAPN6 | c.486G>C p.L162= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- CDH17 | c.804T>A p.G268= | Silent (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- CEACAM20 | c.798G>A p.V266= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs1483104256; called by muse, mutect2
- CHM | c.462C>G p.L154= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2
- CHSY3 | c.1902C>T p.F634= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs760897729, COSV59278296; called by muse, mutect2, varscan2
- CIT | c.2436C>G p.L812= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as COSV99951017; called by muse, mutect2
- CRACD | c.2898G>A p.K966= | Silent (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- CUX2 | c.150G>T p.R50= | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- DCLK3 | c.1368C>A p.L456= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- DYSF | c.4215C>A p.V1405= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- ECT2L | c.1786C>T p.L596= | Silent (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2, varscan2
- ERMARD | c.840C>G p.V280= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs765373004; called by muse, mutect2, varscan2
- EVL | c.1230G>A p.L410= (on ENST00000402714 / NM_001330221.2; = p.L412= on NM_016337.3) | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- FAM104B | c.213T>A p.T71= | Silent (SNP) | VAF 19/262 reads (7%) | called by muse, mutect2
- FAM186A | c.678T>C p.D226= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- FCRL4 | c.1395G>A p.E465= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV54865644, COSV99620377; called by muse, mutect2, varscan2
- FOXS1 | c.618C>A p.L206= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2, varscan2
- FRMPD4 | c.1977C>T p.A659= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV66212011; called by muse, mutect2, varscan2
- GCH1 | c.276C>G p.L92= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs750601953, CD043796; called by muse, mutect2, varscan2
- GOLGA8J | c.1671C>A p.P557= | Silent (SNP) | VAF 8/141 reads (6%) | called by muse, mutect2
- GPR173 | c.309C>A p.A103= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100211958, COSV60233345; called by muse, mutect2, varscan2
- GPRC5C | c.870G>T p.V290= (on ENST00000652232; = p.V245= on NM_018653.4) | Silent (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- HPR | c.402C>T p.I134= | Silent (SNP) | VAF 18/193 reads (9%) | catalogued as COSV57184270; called by muse, mutect2, varscan2
- IFT43 | c.318G>T p.L106= (on ENST00000314067 / NM_001102564.3; = p.L111= on NM_052873.3) | Silent (SNP) | VAF 21/239 reads (9%) | called by muse, mutect2
- IGSF1 | c.3639C>T p.I1213= | Silent (SNP) | VAF 13/158 reads (8%) | catalogued as COSV63837664; called by muse, mutect2
- IKZF3 | c.1275C>T p.Y425= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs765182589, COSV53101138, COSV53102997; called by muse, varscan2
- IL1A | c.546G>A p.V182= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2, varscan2
- INS | c.297C>A p.I99= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV51747133; called by muse, mutect2, varscan2
- ITSN1 | c.2898G>T p.V966= | Silent (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- KCNA3 | c.1173G>A p.L391= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs1366329504, COSV63901784, COSV63902168; called by muse, mutect2
- KIAA1549 | c.1311C>T p.L437= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1340664676; called by muse, mutect2, varscan2
- KIF17 | c.2946A>T p.P982= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- KIF18B | c.276C>T p.S92= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as rs531450616; called by muse, mutect2, varscan2
- KMT2D | c.13276C>T p.L4426= | Silent (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- LAMA4 | c.3216G>A p.V1072= (on ENST00000230538 / NM_001105206.3; = p.V1065= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- LILRB3 | c.843C>T p.F281= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- MAGEE2 | c.1191G>A p.G397= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- MAP4K1 | c.237G>T p.G79= | Silent (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- MAPT | c.1686G>A p.R562= (on ENST00000262410 / NM_001377265.1; = p.R170= on NM_005910.5) | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs776426411; called by muse, mutect2, varscan2
- MCF2L | c.177C>T p.I59= (on ENST00000375608; = p.I27= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- MLXIPL | c.2025C>T p.L675= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs782168651, COSV57667172; called by muse, mutect2, varscan2
- MPI | c.1264C>T p.L422= | Silent (SNP) | VAF 31/199 reads (16%) | called by muse, mutect2, varscan2
- MROH8 | c.360C>T p.F120= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99457095; called by muse, mutect2, varscan2
- MRPL27 | c.99G>A p.K33= | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as COSV56813329; called by muse, mutect2, varscan2
- MTUS2 | c.468G>A p.R156= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs374840836; called by muse, mutect2, varscan2
- MUC16 | c.40579C>T p.L13527= | Silent (SNP) | VAF 23/326 reads (7%) | called by muse, mutect2
- MYRF | c.3150C>T p.V1050= (on ENST00000278836 / NM_001127392.3; = p.V1010= on NM_013279.4) | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as rs1287879354; called by muse, mutect2, varscan2
- N4BP1 | c.1206G>T p.V402= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV52209718; called by muse, mutect2, varscan2
- NAT2 | c.801G>C p.L267= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- NBAS | c.3337C>T p.L1113= | Silent (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- NEB | c.19404C>T p.F6468= | Silent (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- NLRP11 | c.417C>T p.T139= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV64085788; called by muse, mutect2, varscan2
- OGA | c.1470G>T p.A490= | Silent (SNP) | VAF 53/290 reads (18%) | catalogued as COSV63381490; called by muse, mutect2, varscan2
- OR51B2 | c.102G>A p.V34= | Silent (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- OSBP2 | c.762C>G p.L254= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- OXSR1 | c.1572C>T p.L524= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100309340; called by muse, mutect2, varscan2
- P2RY8 | c.696G>C p.R232= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- PARP1 | c.1896G>A p.T632= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs200966933, COSV64691203; called by muse, mutect2, varscan2
- PARP4 | c.2241C>T p.F747= | Silent (SNP) | VAF 19/147 reads (13%) | called by muse, mutect2, varscan2
- PATZ1 | c.1716C>T p.S572= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs776715716; called by muse, varscan2
- PCDHA8 | c.2115C>T p.C705= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV65333833; called by muse, mutect2
- PCK1 | c.813C>T p.T271= | Silent (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- PCNA | c.78C>T p.A26= | Silent (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2
- PDE10A | c.2229G>A p.Q743= | Silent (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- PEX5L | c.49C>T p.L17= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV55850170; called by muse, mutect2
- PGM5 | c.1191G>A p.L397= | Silent (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- PHYH | c.117C>T p.F39= | Silent (SNP) | VAF 44/292 reads (15%) | called by muse, mutect2, varscan2
- PLCD1 | c.153C>T p.I51= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- PLEC | c.12084G>A p.Q4028= (on ENST00000322810 / NM_201380.4; = p.Q3918= on NM_000445.5) | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- PNPLA7 | c.627G>A p.A209= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as rs768304170; called by muse, mutect2, varscan2
- POLE | c.2766C>T p.V922= | Silent (SNP) | VAF 15/139 reads (11%) | called by muse, mutect2
- POLR2A | c.510G>A p.E170= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- POTEI | c.201C>T p.H67= | Silent (SNP) | VAF 19/190 reads (10%) | catalogued as rs1414165759; called by muse, mutect2, varscan2
- PPP1R2B | c.135G>A p.Q45= | Silent (SNP) | VAF 37/220 reads (17%) | called by muse, mutect2, varscan2
- PRDM7 | c.1245G>A p.Q415= | Silent (SNP) | VAF 33/198 reads (17%) | called by muse, mutect2, varscan2
- PRTG | c.267T>C p.S89= | Silent (SNP) | VAF 18/168 reads (11%) | catalogued as COSV66837926; called by muse, mutect2
- PTPN21 | c.156G>T p.V52= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- RAD51AP2 | c.3318A>G p.L1106= | Silent (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2
- REG1A | c.483C>A p.V161= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- RESP18 | c.255G>T p.V85= | Silent (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- RNF10 | c.2148G>T p.L716= | Silent (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2
- SCN2A | c.5517C>G p.L1839= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99330033; called by muse, mutect2, varscan2
- SIRPA | c.789G>C p.V263= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- SLC22A14 | c.1200G>C p.L400= | Silent (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2
- SLC45A4 | c.1524G>C p.L508= (on ENST00000517878 / NM_001286646.2; = p.L457= on NM_001080431.2) | Silent (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- SLITRK2 | c.1047G>A p.Q349= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- SPTBN2 | c.1983G>A p.Q661= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- STAG3 | c.3057C>G p.L1019= | Silent (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- STEAP4 | c.234C>A p.I78= | Silent (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- STK31 | c.2523T>A p.G841= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- STK36 | c.2667G>C p.L889= | Silent (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- STS | c.123G>A p.G41= | Silent (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- TBC1D15 | c.192C>G p.L64= | Silent (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- TBC1D5 | c.243G>A p.L81= | Silent (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- TBC1D8 | c.768G>A p.L256= | Silent (SNP) | VAF 8/66 reads (12%) | called by mutect2, varscan2
- TLN1 | c.291G>T p.V97= | Silent (SNP) | VAF 43/157 reads (27%) | called by muse, mutect2, varscan2
- TMEM132B | c.2046C>T p.I682= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs755168399, COSV54756898, COSV54762832; called by muse, mutect2, varscan2
- TMEM247 | c.252C>A p.G84= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV101417741; called by muse, mutect2, varscan2
- TMEM39A | c.1365C>G p.L455= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV59901345; called by muse, mutect2, varscan2
- TMTC2 | c.849G>A p.L283= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1486785317, COSV58279123; called by muse, mutect2, varscan2
- TNS2 | c.1056C>T p.I352= (on ENST00000314250 / NM_170754.4; = p.I362= on NM_015319.2) | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV58579108; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1398C>T p.L466= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- TRGV11 | c.195G>A p.K65= | Silent (SNP) | VAF 15/121 reads (12%) | called by muse, mutect2, varscan2
- TSC2 | c.3627G>A p.L1209= | Silent (SNP) | VAF 20/115 reads (17%) | called by muse, varscan2
- TTC6 | c.969C>G p.L323= | Silent (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- UBE3C | c.2619G>A p.L873= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- USH2A | c.14190C>A p.T4730= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs199694401; called by muse, mutect2
- USH2A | c.5073G>T p.L1691= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV56382924; called by muse, mutect2, varscan2
- VPS13D | c.5064G>C p.L1688= | Silent (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- WDR19 | c.454C>T p.L152= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2, varscan2
- XIRP2 | c.5661G>T p.T1887= (on ENST00000628543; = p.T2062= on NM_152381.6) | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.369G>T p.R123= | Silent (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- ZFAND4 | c.1464G>A p.V488= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV60862155; called by muse, mutect2
- ZFP64 | c.30C>T p.F10= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV53799418; called by muse, mutect2, varscan2
- ZNF318 | c.6189A>G p.E2063= | Silent (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- ABI3BP | c.1577-8519C>A | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- AC093642.3 | n.3194C>T | RNA (SNP) | VAF 9/44 reads (20%) | called by muse, varscan2
- ADSL | c.655-50C>G | Intron (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- AHRR | c.971-14C>T | Intron (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- AP001496.2 | n.743G>A | RNA (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- ARRDC3 | c.*15G>A | 3'UTR (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- ATP6V0A1 | c.2421-569C>T | Intron (SNP) | VAF 33/195 reads (17%) | called by muse, mutect2, varscan2
- BEAN1 | c.25+37C>A | Intron (SNP) | VAF 14/128 reads (11%) | called by muse, varscan2
- BX119917.1 | n.154G>A | RNA (SNP) | VAF 5/27 reads (19%) | catalogued as rs997309594; called by muse, mutect2, varscan2
- BZW1 | c.-10-345G>C | Intron (SNP) | VAF 11/141 reads (8%) | called by muse, mutect2
- CACNA1F | c.25+23G>T | Intron (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- CD4 | c.374-57C>T | Intron (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- CD7 | c.612+9G>A | Intron (SNP) | VAF 10/84 reads (12%) | catalogued as rs759998274; called by muse, varscan2
- CHKB | c.737-22G>A | Intron (SNP) | VAF 15/135 reads (11%) | called by muse, mutect2, varscan2
- CSF2RA | c.1125+108C>A | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- CUL4B | c.68-808C>G | Intron (SNP) | VAF 5/33 reads (15%) | called by muse, varscan2
- DLG3 | c.1773+858C>T | Intron (SNP) | VAF 16/152 reads (11%) | called by muse, mutect2
- DOCK7 | c.*57G>A | 3'UTR (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- EEF1AKMT3 | c.289+1557C>T | Intron (SNP) | VAF 21/157 reads (13%) | catalogued as rs772405042, COSV99141567; called by muse, mutect2, varscan2
- ERAL1 | c.598+9C>T | Intron (SNP) | VAF 17/129 reads (13%) | called by muse, varscan2
- FAM126A | c.-221G>T | 5'UTR (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- FAM126A | c.-222G>T | 5'UTR (SNP) | VAF 10/45 reads (22%) | catalogued as COSV101300018; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055750 G>A | 3'Flank (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- FAM157A | n.53C>A | RNA (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- FAM183BP | n.1277C>G | RNA (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- FCGR3A | c.-44-46G>A | Intron (SNP) | VAF 20/92 reads (22%) | catalogued as COSV63460006; called by muse, mutect2, varscan2
- GANC | c.202-3762G>C | Intron (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- GOLGA2 | c.171+1025G>T | Intron (SNP) | VAF 14/69 reads (20%) | catalogued as COSV60793235; called by muse, mutect2, varscan2
- GP6 | c.*251C>G | 3'UTR (SNP) | VAF 14/118 reads (12%) | catalogued as rs555783596; called by muse, varscan2
- GSPT1 | c.-63+98G>A | Intron (SNP) | VAF 20/124 reads (16%) | catalogued as rs372895407; called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1289G>A | RNA (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1288T>A | RNA (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- HLA-J | n.1200+179C>T | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as rs375602993; called by muse, mutect2, varscan2
- HMGB1P1 | n.618_620dup | RNA (INS) | VAF 7/59 reads (12%) | catalogued as rs748925246; called by mutect2, varscan2*
- HSP90AA4P | n.1933del | RNA (DEL) | VAF 15/129 reads (12%) | called by mutect2, pindel, varscan2
- IFT88 | c.2096-171A>G | Intron (SNP) | VAF 9/139 reads (6%) | called by muse, mutect2
- IGFN1 | c.1242-1233G>T | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- IL9R | c.-54C>T | 5'UTR (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- ITGA2B | c.625-17C>G | Intron (SNP) | VAF 18/117 reads (15%) | called by muse, mutect2, varscan2
- KLF1 | c.-12C>A | 5'UTR (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- LILRB5 | c.1256-24C>A | Intron (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- LINC01148 | n.458A>T | RNA (SNP) | VAF 9/27 reads (33%) | called by muse, varscan2
- LINC01619 | n.552G>T | RNA (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- LYRM7 | c.*6C>G | 3'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- MAP4 | c.1999+2978C>G | Intron (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- MAPK10 | c.1138+9T>A | Intron (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- MARK2 | c.1961+43C>G | Intron (SNP) | VAF 6/22 reads (27%) | catalogued as rs773479141, COSV59285047; called by muse, varscan2
- MATK | c.-9C>G | 5'UTR (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- MFN2 | c.1160+30G>C | Intron (SNP) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- MROH1 | c.-22G>A | 5'UTR (SNP) | VAF 6/56 reads (11%) | called by muse, varscan2
- NDUFV1 | c.73-29C>G | Intron (SNP) | VAF 13/84 reads (15%) | catalogued as rs192791762; called by muse, mutect2, varscan2
- OR2M1P | n.531C>A | RNA (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- OR7E5P | n.486G>A | RNA (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- PCDHB6 | chr5:141156151 T>C | 3'Flank (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2
- PDZRN4 | c.844-68480G>C | Intron (SNP) | VAF 16/130 reads (12%) | catalogued as COSV100115058; called by muse, varscan2
- PLAC8L1 | c.-23A>T | 5'UTR (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- PSMC3IP | c.-8G>A | 5'UTR (SNP) | VAF 13/108 reads (12%) | catalogued as rs200632502; called by muse, mutect2, varscan2
- RBL2 | c.993-400A>G | Intron (SNP) | VAF 6/62 reads (10%) | catalogued as rs1426585233; called by muse, mutect2, varscan2
- RBM33 | c.3375+92G>C | Intron (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- RIN3 | c.250-987G>A | Intron (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- RNF103 | c.-970C>A | 5'UTR (SNP) | VAF 6/27 reads (22%) | catalogued as rs1190065163; called by muse, mutect2, varscan2
- RNF8 | c.112-1205C>G | Intron (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- RNGTT | chr6:88965684 C>G | 5'Flank (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- RSPO2 | c.-1G>C | 5'UTR (SNP) | VAF 16/57 reads (28%) | catalogued as rs202185418; called by muse, mutect2, varscan2
- SCAF11 | c.220-4364C>T | Intron (SNP) | VAF 5/98 reads (5%) | catalogued as rs1036237175; called by muse, mutect2
- SEPSECS | c.115-514G>T | Intron (SNP) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- SEPTIN10 | c.30+656C>G | Intron (SNP) | VAF 13/72 reads (18%) | catalogued as rs1435529814; called by muse, mutect2, varscan2
- SLA | c.-40-112C>T | Intron (SNP) | VAF 46/284 reads (16%) | called by muse, mutect2, varscan2
- SPATA21 | c.*32C>G | 3'UTR (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.3531G>T | RNA (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- STEAP1 | c.762+935G>A | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- THUMPD1 | c.-37G>C | 5'UTR (SNP) | VAF 11/54 reads (20%) | catalogued as rs368802068; called by muse, mutect2, varscan2
- UBE2D4 | c.24+1525G>C | Intron (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- UBE2N | c.277+63C>G | Intron (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- UMPS | c.*563G>A | 3'UTR (SNP) | VAF 4/14 reads (29%) | catalogued as rs542210532; called by mutect2, varscan2
- ZNF213 | chr16:3146026 G>T | 3'Flank (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- ZNF418 | c.6+1306G>T | Intron (SNP) | VAF 14/66 reads (21%) | catalogued as rs1173313349; called by muse, mutect2, varscan2
- ZNF667 | c.254-6851C>G | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
